MMRF case MMRF_1167 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d932945e-727e-4d78-9ae3-1ea119ede6f5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 950 days (2.6 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.3 years (27,123 days); ISS stage: II; Days to last known disease status: 950 days (2.6 years); Days to last follow up: 950 days (2.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 5 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 9 days; Days to treatment end: 10 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 12 days; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 12 days; Days to treatment end: 13 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 16 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 293 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 630 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 293 days; Days to treatment end: 630 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 630 days (1.7 years); Days to treatment end: 834 days (2.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 630 days (1.7 years); Days to treatment end: 819 days (2.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 834 days (2.3 years); Days to treatment end: 946 days (2.6 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 950.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 11 (ECOG 3): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.6 mg/dL; Immunoglobulin G 24.4 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 26 g/L; Total Protein 6.8 g/dL; Glucose 7.65 mmol/L; C-Reactive Protein 0.5 mg/dL.
- Day 92: M Protein 0.2 g/dL; Hemoglobin 7.63 mmol/L; Leukocytes 10.6 ×10⁹/L; Absolute Neutrophil 8.9 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 32 g/L; Total Protein 6.9 g/dL; Glucose 6.16 mmol/L.
- Day 184: M Protein 0 g/dL; Lactate Dehydrogenase 4.42 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 6.5 g/dL; Glucose 6.49 mmol/L.
- Day 275: Serum Free Immunoglobulin Light Chain, Kappa 9.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.2 mg/dL; Beta 2 Microglobulin 2.5 µg/mL; Hemoglobin 8.56 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 7.4 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 3.91 mmol/L.
- Day 363: Serum Free Immunoglobulin Light Chain, Kappa 11.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 17.9 mg/dL; Hemoglobin 9.05 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 8.2 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L.
- Day 467: Serum Free Immunoglobulin Light Chain, Kappa 13.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 32.1 mg/dL; Hemoglobin 9.49 mmol/L; Leukocytes 10.3 ×10⁹/L; Absolute Neutrophil 8.3 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 7.8 g/dL; Glucose 5.28 mmol/L.
- Day 547: Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 38.9 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 8.1 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 4.57 mmol/L.
- Day 630: M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.6 mg/dL; Hemoglobin 8.62 mmol/L; Leukocytes 12 ×10⁹/L; Absolute Neutrophil 9.7 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Total Protein 6.9 g/dL; Glucose 5.39 mmol/L.
- Day 728: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.6 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.2 mmol/L; Glucose 5.06 mmol/L.
- Day 919 (ECOG 3): Serum Free Immunoglobulin Light Chain, Kappa 6.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.26 mg/dL; Hemoglobin 6.51 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 7.1 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Glucose 9.08 mmol/L.

Other clinical attributes
- Day 11: Weight: 111 kg; Height: 183 cm.

Biospecimens (2 samples)
- Sample MMRF_1167_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 11 days.
- Sample MMRF_1167_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 11 days.
